Somatic mutation profile of cancer-model specimen HCM-BROD-0219-C15-85A (3D Organoid, passage 8; aliquot HCM-BROD-0219-C15-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-BROD-0219-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.1 years (24,891 days).
Specimen HCM-BROD-0219-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40081139-10f8-417e-ad92-e09e4f6e7fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0219-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0219-C15-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/934472a4-0df7-4523-b32e-22227f0aa37e

The open-access MAF lists 290 somatic variants for this specimen: 208 protein-altering or splice-affecting, 67 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 67, Nonsense Mutation 8, Intron 8, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 2, 3'UTR 2, RNA 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTNBP1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 74/712 reads (10%) | catalogued as rs104893945, CM032218; ClinVar: pathogenic; called by muse, varscan2
- MMUT | c.29dup p.L10Ffs*39 | Frame Shift Ins (INS) | VAF 64/372 reads (17%) | catalogued as rs1437477079; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 481/481 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3595G>A p.A1199T (on ENST00000326724 / NM_001080395.3; = p.A1096T on NM_004920.2) | Missense Mutation (SNP) | VAF 255/1175 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs757323806; called by muse, mutect2, varscan2
- ACLY | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 383/551 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1252881714, COSV61252734; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3040G>C p.E1014Q | Missense Mutation (SNP) | VAF 406/722 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV54461199; called by muse, mutect2, varscan2
- AL117348.2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 378/818 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766372196, COSV55283856; called by muse, mutect2, varscan2
- ANGEL2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.701); catalogued as rs144294999; called by muse, mutect2, varscan2
- APLNR | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 361/924 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as rs147193169, COSV57243545; called by muse, mutect2, varscan2
- ARFGEF1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs763728256; called by muse, mutect2, varscan2
- ARMC5 | c.344C>G p.S115W | Missense Mutation (SNP) | VAF 240/1131 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.686); catalogued as rs771753877; called by muse, mutect2, varscan2
- B3GNT2 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 47/1880 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV100114087; called by muse, mutect2
- BRDT | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV104423744; called by muse, mutect2, varscan2
- CDKL3 | c.872T>G p.F291C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54740627; called by muse, mutect2, varscan2
- CEP290 | c.7083G>C p.Q2361H | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs201801456; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 78/141 reads (55%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CHRNA4 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 238/1760 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs1057521949; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL19A1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750042587, COSV100505807, COSV59585071; called by muse, mutect2, varscan2
- COL6A6 | c.5930G>T p.G1977V | Missense Mutation (SNP) | VAF 87/411 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV62026033; called by muse, mutect2, varscan2
- CPS1 | c.4415T>G p.L1472R | Missense Mutation (SNP) | VAF 186/488 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs756635859, COSV51802426; called by muse, mutect2, varscan2
- CPXM2 | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 129/213 reads (61%) | catalogued as rs147055269; called by muse, mutect2, varscan2
- DAAM2 | c.1787A>G p.K596R | Missense Mutation (SNP) | VAF 179/514 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV99225596; called by muse, mutect2, varscan2
- DCAF13 | c.12G>T p.K4N | Missense Mutation (SNP) | VAF 30/836 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52567606; called by muse, mutect2
- DOCK3 | c.4090T>G p.F1364V | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762521394; called by muse, mutect2, varscan2
- DTNA | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.311); catalogued as rs747872788, COSV51990719; called by muse, mutect2, varscan2
- ERMP1 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 240/241 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs780186073, COSV53036244; called by muse, mutect2, varscan2
- FBLN2 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 183/783 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs746929723, COSV99851726; called by muse, mutect2
- FLG | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 141/650 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs745356634; called by muse, mutect2, varscan2
- FOXK2 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 116/873 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.903); catalogued as rs200173626, COSV58878141; called by muse, mutect2, varscan2
- FOXRED1 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs377464580; called by muse, mutect2
- FZD8 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 198/792 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV101020280; called by muse, mutect2, varscan2
- GREB1 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 120/578 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs778284838, COSV52194132; called by muse, mutect2, varscan2
- HAUS6 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65840282; called by muse, mutect2, varscan2
- HOXD9 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 395/851 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs373207184; called by muse, mutect2, varscan2
- ITSN2 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 347/347 reads (100%) | catalogued as rs1258919694; called by muse, mutect2, varscan2
- JARID2 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 1197/1601 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs756644508, COSV59187991; called by muse, mutect2, varscan2
- KCTD20 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 222/697 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1397229307; called by muse, mutect2, varscan2
- KHDC3L | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 109/600 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64869115; called by muse, mutect2, varscan2
- LLGL2 | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 108/724 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99390699; called by muse, mutect2, varscan2
- LRFN5 | c.2095C>A p.P699T | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53265920; called by muse, mutect2, varscan2
- MARF1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 116/502 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1302878167; called by muse, mutect2, varscan2
- MED15 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 215/682 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99487260, COSV99487542; called by muse, varscan2
- MIER1 | c.446G>A p.R149H (on ENST00000355356 / NM_001077701.3; = p.R166H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs199596911; called by muse, mutect2, varscan2
- MUC12 | c.5489C>T p.T1830I (on ENST00000379442; = p.T1687I on NM_001164462.1) | Missense Mutation (SNP) | VAF 40/1148 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1354630688, COSV65189616; called by muse, mutect2
- NAALADL2 | c.2171C>A p.A724E | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs755034163; called by muse, mutect2, varscan2
- NOVA1 | c.135C>T p.G45= | Splice Region (SNP) | VAF 301/301 reads (100%) | catalogued as COSV57483086; called by muse, mutect2, varscan2
- NR1H2 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 109/552 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772703025, COSV53800669; called by muse, mutect2, varscan2
- OR10J1 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 261/535 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV71128784; called by muse, mutect2, varscan2
- OR13C8 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 222/362 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771734811, COSV58610720; called by muse, mutect2, varscan2
- OR9G4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 294/784 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs759952299, COSV57248107; called by muse, mutect2
- PEX11B | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 175/781 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as rs369527712; called by muse, mutect2, varscan2
- PHF20L1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 163/234 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs780399495; called by muse, mutect2, varscan2
- PHOSPHO1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 261/1182 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.448); catalogued as rs1170662264; called by muse, mutect2, varscan2
- PLXNC1 | c.230C>G p.S77W | Missense Mutation (SNP) | VAF 886/886 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99313065; called by muse, mutect2, varscan2
- PSKH1 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 330/889 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52123147; called by muse, mutect2, varscan2
- PSMF1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 168/670 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs778112172; called by muse, mutect2, varscan2
- PTCH2 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 374/374 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs145383991; called by muse, varscan2
- PYDC2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1248687866; called by muse, mutect2, varscan2
- QSER1 | c.4778A>G p.K1593R (on ENST00000399302; = p.K1722R on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs749512206; called by muse, mutect2, varscan2
- RBBP8NL | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 253/1051 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371268446; called by muse, mutect2, varscan2
- RBMXL3 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 231/329 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV57747437; called by muse, mutect2, varscan2
- SAT2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as rs776874716; called by muse, mutect2
- SCN1A | c.5942C>T p.A1981V (on ENST00000303395 / NM_001202435.3; = p.A1970V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/425 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs148986284; called by muse, mutect2, varscan2
- SEMA6A | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.49); catalogued as rs377316252; called by muse, mutect2
- SETX | c.7741C>T p.H2581Y | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs530686162; called by muse, mutect2, varscan2
- SH2D2A | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 427/690 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs541076063, COSV104427299; called by muse, varscan2
- SHISA9 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); catalogued as rs1288139077, COSV69633139; called by muse, mutect2, varscan2
- SLC2A4RG | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 103/867 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55516187; called by muse, mutect2, varscan2
- SLC39A5 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 177/680 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565601214; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SP3 | c.469G>C p.G157R | Missense Mutation (SNP) | VAF 236/391 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs750977205; called by muse, mutect2, varscan2
- SPSB4 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 206/640 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1026476200; called by muse, varscan2
- SPTA1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 191/505 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV63751058; called by muse, mutect2, varscan2
- SRSF10 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1386013391; called by muse, mutect2, varscan2
- STAM | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782345032; called by muse, mutect2, varscan2
- STARD13 | c.659C>T p.P220L (on ENST00000336934 / NM_001243476.3; = p.P102L on NM_052851.3) | Missense Mutation (SNP) | VAF 118/906 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs199932998; called by muse, mutect2, varscan2
- TLE4 | c.933C>A p.S311R | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as COSV54627411; called by muse, mutect2, varscan2
- TNFSF10 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | catalogued as rs200693533; called by muse, mutect2, varscan2
- TRAF3IP1 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375052092; called by muse, mutect2, varscan2
- VPS13B | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 99/466 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs773391550; called by muse, mutect2, varscan2
- ZBTB42 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 594/895 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100696457; called by muse, mutect2, varscan2
- ZEB2 | c.1372A>C p.S458R | Missense Mutation (SNP) | VAF 114/622 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV57960761; called by muse, mutect2, varscan2
- ZFPM2 | c.2528C>T p.T843M | Missense Mutation (SNP) | VAF 121/664 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); catalogued as rs1448468136, CM147409, COSV65875560; called by muse, mutect2, varscan2
- ZNF117 | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV51426208; called by muse, mutect2, varscan2
- ZNF541 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 228/890 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1450591453, COSV54542555; called by muse, mutect2, varscan2
- ZNF614 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs748616123, COSV54546581; called by muse, mutect2, varscan2
- ABHD16B | c.848T>A p.M283K | Missense Mutation (SNP) | VAF 626/1449 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ACP1 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ADGRV1 | c.5693C>T p.P1898L | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AGTR1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 96/392 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- APEH | c.1786T>G p.L596V | Missense Mutation (SNP) | VAF 157/375 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- APOBR | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 182/834 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ASXL3 | c.4044C>A p.N1348K | Missense Mutation (SNP) | VAF 138/452 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN3L | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- BANK1 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- BCOR | c.4800_4807del p.F1600Lfs*5 (on ENST00000378444 / NM_001123385.2; = p.F1566Lfs*5 on NM_017745.6) | Frame Shift Del (DEL) | VAF 180/182 reads (99%) | called by mutect2, pindel, varscan2
- BRCA2 | c.9289T>C p.C3097R | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by mutect2, varscan2
- CCDC157 | c.2150A>T p.D717V | Missense Mutation (SNP) | VAF 489/739 reads (66%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD164 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 128/1234 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD22 | c.1235A>C p.E412A | Missense Mutation (SNP) | VAF 98/458 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CEP43 | c.822G>T p.R274S | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.9252G>T p.Q3084H | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CHRNB2 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 568/947 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CNTN6 | c.1355A>T p.Q452L | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNTNAP5 | c.2492dup p.N831Kfs*5 | Frame Shift Ins (INS) | VAF 71/272 reads (26%) | called by mutect2, pindel, varscan2
- COG8 | c.725A>C p.E242A | Missense Mutation (SNP) | VAF 180/828 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL14A1 | c.4105G>T p.V1369F | Missense Mutation (SNP) | VAF 252/331 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- COL4A4 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CORIN | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4A | c.1863A>T p.K621N | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIRAS3 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 77/569 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- DLGAP2 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 115/410 reads (28%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- DNAH17 | c.4718_4722del p.T1573Kfs*14 | Frame Shift Del (DEL) | VAF 109/632 reads (17%) | called by mutect2, pindel, varscan2
- EFEMP1 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 210/508 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- EGFLAM | c.2456G>A p.C819Y | Missense Mutation (SNP) | VAF 412/500 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3K | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 136/539 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENPP1 | c.869T>G p.L290R | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EOLA2 | c.257T>A p.L86H | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- EPB41L4A | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESS2 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 343/507 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FDXR | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 130/552 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHAD1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 251/251 reads (100%) | called by muse, mutect2, varscan2
- FOXD4L6 | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 199/1423 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FRAS1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 446/447 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FSIP2 | c.19432G>A p.D6478N | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAL3ST4 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 137/752 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GLYR1 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- GOLGA6L6 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 66/610 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR27 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 144/257 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR45 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 166/1131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRB2 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 20/654 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- GRIK4 | c.2660T>C p.L887P | Missense Mutation (SNP) | VAF 412/1168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GRIN3B | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 178/717 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.348); called by muse, varscan2
- GRIN3B | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 251/992 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.788); called by muse, varscan2
- HELZ | c.2831A>G p.K944R | Missense Mutation (SNP) | VAF 208/542 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- HGS | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 241/921 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- INPP5D | c.443A>G p.E148G (on ENST00000445964 / NM_001017915.3; = p.E147G on NM_005541.5) | Missense Mutation (SNP) | VAF 128/699 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGB1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITK | c.755T>G p.L252R | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KDM5A | c.4778C>G p.S1593* | Nonsense Mutation (SNP) | VAF 986/986 reads (100%) | called by muse, mutect2, varscan2
- KIF13A | c.2869C>G p.R957G | Missense Mutation (SNP) | VAF 86/1414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIF4A | c.33A>T p.R11S | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.169); called by mutect2, varscan2
- KIRREL3 | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 344/904 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LAMA1 | c.3727T>C p.F1243L | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LCA5 | c.81T>G p.F27L | Missense Mutation (SNP) | VAF 426/548 reads (78%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LGALS3 | c.558_561del p.R186Sfs*27 | Frame Shift Del (DEL) | VAF 102/108 reads (94%) | called by mutect2, pindel, varscan2
- LHFPL1 | c.232A>C p.S78R | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC49 | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- LSM7 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 302/578 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MOCS1 | c.974A>T p.N325I | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXRA7 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 399/628 reads (64%) | PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MYOM2 | c.2558A>C p.E853A | Missense Mutation (SNP) | VAF 127/386 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- N4BP2 | c.2384A>C p.K795T | Missense Mutation (SNP) | VAF 140/202 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- NEFL | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 195/406 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NKX6-1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 191/651 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NNT | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 122/480 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR2AJ1 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 138/265 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2G6 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 140/550 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- P4HA3 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 205/512 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB11 | c.354A>T p.Q118H | Missense Mutation (SNP) | VAF 117/357 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PFKM | c.274T>A p.F92I | Missense Mutation (SNP) | VAF 348/495 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHA6 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 310/659 reads (47%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PLEKHO1 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 174/758 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F2 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 156/2283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP2R1B | c.1435A>G p.M479V | Missense Mutation (SNP) | VAF 185/450 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKACG | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 196/987 reads (20%) | called by muse, mutect2, varscan2
- PTPRM | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PURA | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 395/583 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PUS3 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 199/571 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD50 | c.1773G>T p.R591S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- RPAP1 | c.1748T>G p.V583G | Missense Mutation (SNP) | VAF 80/490 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SACS | c.5568C>G p.I1856M | Missense Mutation (SNP) | VAF 391/596 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SCN1A | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 165/619 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SEC13 | c.310T>C p.S104P (on ENST00000350697 / NM_183352.3; = p.S107P on NM_030673.4) | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L5 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 421/859 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SFI1 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 202/360 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3PXD2B | c.956G>C p.S319T | Missense Mutation (SNP) | VAF 137/1008 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHCBP1 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 265/644 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SLC22A10 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 180/477 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC33A1 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SP1 | c.2057T>G p.F686C (on ENST00000327443 / NM_138473.3; = p.F679C on NM_003109.1) | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPZ1 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SRCAP | c.3945A>C p.Q1315H | Missense Mutation (SNP) | VAF 257/499 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUSD4 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 314/665 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYT3 | c.1145T>A p.L382Q | Missense Mutation (SNP) | VAF 187/754 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAB2 | c.244T>G p.L82V | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TANC1 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TICAM1 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 168/764 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TIGIT | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 104/376 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TMEM98 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 125/445 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TMPRSS6 | c.1922A>T p.K641M | Missense Mutation (SNP) | VAF 435/659 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRAF3IP3 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TRIM7 | c.586T>G p.S196A | Missense Mutation (SNP) | VAF 143/892 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- TRMT13 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRPA1 | c.2919G>T p.L973F | Missense Mutation (SNP) | VAF 92/587 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TRPS1 | c.1497C>A p.D499E (on ENST00000220888 / NM_001330599.2; = p.D512E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/471 reads (20%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.792A>C p.R264S | Missense Mutation (SNP) | VAF 121/735 reads (16%) | PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TYR | c.1011T>A p.N337K | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPF1 | c.1527G>C p.K509N (on ENST00000599848 / NM_001297549.2; = p.K498N on NM_002911.4) | Missense Mutation (SNP) | VAF 147/677 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WHAMM | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 124/714 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ZFHX2 | c.6650C>T p.A2217V | Missense Mutation (SNP) | VAF 690/691 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZFPL1 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 171/953 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMAT1 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 145/146 reads (99%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF263 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 130/565 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ZNF644 | c.2146G>C p.D716H | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ZNF722P | c.623C>G p.T208S | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF80 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ZSCAN18 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 139/547 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ABCA5 | c.3435G>A p.A1145= | Silent (SNP) | VAF 58/88 reads (66%) | catalogued as rs761263417, COSV67016504; called by muse, varscan2
- ABHD11 | c.834G>A p.E278= | Silent (SNP) | VAF 137/511 reads (27%) | called by muse, mutect2, varscan2
- AC008397.2 | c.747C>A p.S249= | Silent (SNP) | VAF 103/459 reads (22%) | called by muse, mutect2, varscan2
- ACTR5 | c.660T>G p.G220= | Silent (SNP) | VAF 242/923 reads (26%) | called by muse, mutect2, varscan2
- ADCY3 | c.2035C>T p.L679= | Silent (SNP) | VAF 449/450 reads (100%) | called by muse, mutect2, varscan2
- ADD2 | c.528T>G p.S176= | Silent (SNP) | VAF 119/629 reads (19%) | called by muse, mutect2, varscan2
- ADRA1A | c.489C>T p.F163= | Silent (SNP) | VAF 211/405 reads (52%) | catalogued as COSV52358685; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1404C>T p.F468= | Silent (SNP) | VAF 147/812 reads (18%) | catalogued as COSV52269016; called by muse, mutect2, varscan2
- BHLHE23 | c.270C>T p.D90= (on ENST00000370346; = p.D106= on NM_080606.4) | Silent (SNP) | VAF 182/894 reads (20%) | catalogued as rs1279666290; called by muse, mutect2, varscan2
- C19orf73 | c.150G>T p.A50= | Silent (SNP) | VAF 253/1274 reads (20%) | called by muse, mutect2, varscan2
- CEACAM18 | c.669G>A p.V223= | Silent (SNP) | VAF 10/326 reads (3%) | called by muse, mutect2
- CFAP54 | c.3501G>A p.L1167= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs1039153678; called by muse, mutect2
- CHSY1 | c.1242G>A p.E414= | Silent (SNP) | VAF 142/816 reads (17%) | called by muse, mutect2, varscan2
- CLUH | c.93G>T p.P31= (on ENST00000435359; = p.P69= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 557/559 reads (100%) | called by muse, mutect2, varscan2
- CYP51A1 | c.69G>A p.A23= | Silent (SNP) | VAF 154/966 reads (16%) | called by muse, mutect2, varscan2
- DSG2 | c.1566A>G p.G522= | Silent (SNP) | VAF 128/566 reads (23%) | called by muse, mutect2, varscan2
- ELFN1 | c.549G>A p.S183= | Silent (SNP) | VAF 685/1190 reads (58%) | catalogued as rs201038581; called by muse, mutect2, varscan2
- EML2 | c.117A>T p.A39= | Silent (SNP) | VAF 146/579 reads (25%) | called by muse, mutect2, varscan2
- EPHA3 | c.1488C>A p.I496= | Silent (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- ERICH1 | c.642C>T p.S214= | Silent (SNP) | VAF 1068/1276 reads (84%) | catalogued as rs755945043; called by muse, mutect2, varscan2
- FLNC | c.2463C>T p.I821= | Silent (SNP) | VAF 196/365 reads (54%) | called by muse, mutect2, varscan2
- GABRR3 | c.880A>C p.R294= | Silent (SNP) | VAF 166/166 reads (100%) | called by muse, mutect2, varscan2
- GAPDH | c.504T>C p.F168= | Silent (SNP) | VAF 449/731 reads (61%) | called by muse, mutect2, varscan2
- GLDC | c.96G>A p.P32= | Silent (SNP) | VAF 280/510 reads (55%) | called by muse, mutect2, varscan2
- GOLGA3 | c.234T>C p.P78= | Silent (SNP) | VAF 177/647 reads (27%) | catalogued as rs893884871; called by muse, mutect2, varscan2
- HDC | c.970C>T p.L324= | Silent (SNP) | VAF 109/577 reads (19%) | called by muse, mutect2, varscan2
- HGFAC | c.1557C>T p.P519= | Silent (SNP) | VAF 580/581 reads (100%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.36C>T p.L12= | Silent (SNP) | VAF 179/528 reads (34%) | catalogued as rs1418788464, COSV51443904; called by muse, mutect2, varscan2
- HRH1 | c.780G>C p.L260= | Silent (SNP) | VAF 147/609 reads (24%) | called by muse, mutect2, varscan2
- ICMT | c.636T>G p.S212= | Silent (SNP) | VAF 97/342 reads (28%) | called by muse, mutect2, varscan2
- IGDCC3 | c.1365C>T p.I455= | Silent (SNP) | VAF 131/629 reads (21%) | catalogued as rs139714581; called by muse, mutect2, varscan2
- IL11 | c.69G>A p.G23= | Silent (SNP) | VAF 28/888 reads (3%) | called by muse, mutect2
- ITIH2 | c.2226T>G p.G742= | Silent (SNP) | VAF 67/287 reads (23%) | called by muse, mutect2, varscan2
- KCND2 | c.894C>T p.F298= | Silent (SNP) | VAF 135/260 reads (52%) | catalogued as rs1290518120, COSV58605434; called by muse, mutect2, varscan2
- KCNN1 | c.57C>T p.G19= | Silent (SNP) | VAF 485/959 reads (51%) | catalogued as rs554018689, COSV55838758; called by muse, mutect2, varscan2
- LAMB1 | c.3555C>G p.L1185= | Silent (SNP) | VAF 278/686 reads (41%) | called by muse, mutect2, varscan2
- LRP5 | c.3924T>C p.G1308= | Silent (SNP) | VAF 199/1054 reads (19%) | called by muse, mutect2, varscan2
- MAN2B1 | c.793A>C p.R265= | Silent (SNP) | VAF 112/536 reads (21%) | called by muse, mutect2, varscan2
- MAP1B | c.4290A>G p.E1430= | Silent (SNP) | VAF 121/252 reads (48%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.1332C>T p.S444= | Silent (SNP) | VAF 173/1087 reads (16%) | catalogued as rs755355022, COSV99571608; called by muse, mutect2, varscan2
- MUC12 | c.13392C>A p.T4464= (on ENST00000379442; = p.T4321= on NM_001164462.1) | Silent (SNP) | VAF 114/3414 reads (3%) | catalogued as rs748613444; called by muse, mutect2
- MYH2 | c.1920G>A p.K640= | Silent (SNP) | VAF 81/353 reads (23%) | catalogued as COSV55443136, COSV55447644; called by muse, mutect2, varscan2
- MYO15A | c.1923G>A p.A641= | Silent (SNP) | VAF 214/652 reads (33%) | catalogued as rs1182485387; called by muse, mutect2, varscan2
- NECTIN3 | c.462G>A p.P154= | Silent (SNP) | VAF 50/203 reads (25%) | catalogued as rs184658645; called by muse, mutect2, varscan2
- NEFL | c.1344A>G p.Q448= | Silent (SNP) | VAF 113/286 reads (40%) | called by muse, mutect2, varscan2
- NLRP8 | c.90T>A p.S30= | Silent (SNP) | VAF 121/487 reads (25%) | called by muse, mutect2, varscan2
- NUP98 | c.3201A>G p.E1067= (on ENST00000359171 / NM_001365126.1; = p.E1050= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 204/205 reads (100%) | called by muse, mutect2, varscan2
- OPRK1 | c.225G>T p.V75= | Silent (SNP) | VAF 154/586 reads (26%) | catalogued as rs1354066337, COSV99654448; called by muse, mutect2, varscan2
- PAFAH1B3 | c.183C>G p.L61= | Silent (SNP) | VAF 239/486 reads (49%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2085C>T p.N695= | Silent (SNP) | VAF 190/680 reads (28%) | catalogued as COSV56479305, COSV56507255; called by muse, mutect2, varscan2
- PCDHA12 | c.2004G>A p.S668= | Silent (SNP) | VAF 135/493 reads (27%) | catalogued as COSV56540990; called by muse, mutect2, varscan2
- PCDHB14 | c.2307G>A p.P769= | Silent (SNP) | VAF 125/403 reads (31%) | catalogued as rs147177582; called by muse, mutect2, varscan2
- PHF3 | c.3348C>A p.L1116= | Silent (SNP) | VAF 11/325 reads (3%) | called by muse, mutect2
- PLAG1 | c.141G>A p.E47= | Silent (SNP) | VAF 85/348 reads (24%) | catalogued as COSV57614746; called by muse, mutect2, varscan2
- PLEKHH2 | c.2157T>G p.S719= | Silent (SNP) | VAF 67/315 reads (21%) | called by muse, mutect2, varscan2
- PTX4 | c.822T>G p.V274= (on ENST00000447419 / NM_001328608.2; = p.V269= on NM_001013658.1) | Silent (SNP) | VAF 109/487 reads (22%) | called by muse, mutect2, varscan2
- RAI1 | c.1419A>T p.P473= | Silent (SNP) | VAF 459/675 reads (68%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.2298C>T p.N766= | Silent (SNP) | VAF 306/550 reads (56%) | called by muse, mutect2
- SOX12 | c.306G>A p.A102= | Silent (SNP) | VAF 368/1302 reads (28%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1419G>A p.E473= | Silent (SNP) | VAF 235/235 reads (100%) | called by muse, mutect2, varscan2
- TBCB | c.390C>T p.L130= | Silent (SNP) | VAF 200/818 reads (24%) | catalogued as rs747265303; called by muse, mutect2, varscan2
- TLX2 | c.391C>A p.R131= | Silent (SNP) | VAF 23/904 reads (3%) | called by muse, mutect2
- TMEM121B | c.912G>A p.A304= | Silent (SNP) | VAF 121/296 reads (41%) | catalogued as COSV58897211; called by muse, mutect2, varscan2
- TMEM201 | c.900C>T p.V300= | Silent (SNP) | VAF 218/649 reads (34%) | called by muse, mutect2, varscan2
- TRHDE | c.1389A>G p.E463= | Silent (SNP) | VAF 230/350 reads (66%) | catalogued as rs752070680, COSV99673128; called by muse, mutect2, varscan2
- ZNF200 | c.759T>A p.T253= | Silent (SNP) | VAF 161/368 reads (44%) | catalogued as COSV67724083; called by muse, mutect2, varscan2
- ZNF782 | c.1209C>T p.F403= | Silent (SNP) | VAF 136/431 reads (32%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-122+672T>C | Intron (SNP) | VAF 139/785 reads (18%) | called by muse, mutect2, varscan2
- AQP10 | c.707+15C>T | Intron (SNP) | VAF 315/1001 reads (31%) | catalogued as rs747841880; called by muse, mutect2, varscan2
- CNTNAP3P2 | n.1145T>G | RNA (SNP) | VAF 139/786 reads (18%) | called by muse, varscan2
- CNTNAP3P2 | n.1230G>A | RNA (SNP) | VAF 148/778 reads (19%) | catalogued as rs868378102; called by muse, varscan2
- CSMD2 | c.67+705C>A | Intron (SNP) | VAF 185/496 reads (37%) | called by muse, mutect2, varscan2
- DPF3 | c.871+3054C>T | Intron (SNP) | VAF 338/338 reads (100%) | catalogued as rs201262416; called by muse, mutect2, varscan2
- FARP1 | c.1414+566G>A | Intron (SNP) | VAF 30/696 reads (4%) | called by muse, mutect2
- FICD | c.302-189C>T | Intron (SNP) | VAF 144/545 reads (26%) | catalogued as rs973083223; called by muse, mutect2, varscan2
- GPR137 | chr11:64284743 A>G | 5'Flank (SNP) | VAF 165/775 reads (21%) | called by muse, mutect2, varscan2
- IL37 | c.145+1377A>G | Intron (SNP) | VAF 239/378 reads (63%) | called by muse, mutect2, varscan2
- MAL2 | c.-1C>A | 5'UTR (SNP) | VAF 28/880 reads (3%) | called by muse, mutect2
- OXSR1 | c.*1340T>C | 3'UTR (SNP) | VAF 148/297 reads (50%) | called by muse, mutect2, varscan2
- PSTK | c.*71T>G | 3'UTR (SNP) | VAF 27/104 reads (26%) | catalogued as rs1333752062; called by muse, mutect2, varscan2
- SLC41A3 | c.274-5375T>C | Intron (SNP) | VAF 151/546 reads (28%) | called by muse, mutect2, varscan2
- TANC1 | c.-1A>G | 5'UTR (SNP) | VAF 67/388 reads (17%) | called by muse, mutect2, varscan2
